Surgical pathology report (de-identified scan), TCGA case TCGA-B2-3924, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-B2-3924-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

Left kidney

CLINICAL NOTES

PRE-OP DIAGNOSIS: Renal mass

GROSS DESCRIPTION

Received fresh in a container labeled "left kidney" is a specimen weighing 688 gm, and spanning an area 19 x 14.5 x 7 cm. The specimen consists of an 11.2 x 6.5 x 5.3 cm kidney, with surrounding yellow adipose tissue. Within the adipose tissue is a slightly fragmented 5.5 x 2.7 x 1.3 cm yellow-orange adrenal gland, without focal lesion in the adrenal gland. The kidney is sectioned, revealing a circumscribed 4.3 x 3.7 x 3.5 cm focally cystic yellow-orange mass, which appears confined to the kidney and is 0.25 cm from the surface of the specimen in its closest extent. Per the clinical request, a portion of tumor and a portion of normal parenchyma are submitted for tissue procurement. The renal pelvis is smooth and tan-white. The parenchyma away from the mass is tan-pink-red with a well-defined corticomedullary junction, with a maximal cortical thickness of 1.2 cm. There are a few cortical cysts with smooth linings compatible with simple cysts, up to 1.2 cm in greatest dimension. RS-10, following fixation.

BLOCK SUMMARY: 1 - vascular and ureteral margins; 2-5 - tumor, including relation to surrounding parenchyma, renal capsule, and surrounding fat; 6 - renal pelvis; 7-9 - kidney away from tumor; 10 -adrenal gland.

MICROSCOPIC DESCRIPTION

The following template summarizes these findings in this case:

[page 2 of 2]
MICROSCOPIC DESCRIPTION

Histologic type: Clear cell renal cell carcinoma
Histologic grade (Fuhrman Nuclear Grade): 2
Primary tumor (pT): pT1b. The tumor is 4.2 cm in greatest dimension
and is limited to kidney.
Margins of resection: Negative for tumor
Regional lymph nodes (pN): pNX
Distant metastasis (pM): pMX
Adrenal gland: Negative for tumor
Vascular invasion: Not identified
Non-neoplastic kidney: Simple cysts. Scattered chronic inflammation.

4

DIAGNOSIS

Kidney and adrenal gland, left, excision
- Clear cell renal cell carcinoma, 4.2 cm in greatest dimension, limited to the kidney, margins negative for malignancy.
- Adrenal gland without specific diagnostic abnormalities.

---- End Of Report ----

Source: NCI Genomic Data Commons file a9ce6b44-2600-4408-87f7-59811cb5940a (TCGA-B2-3924.472B22B5-7589-45EC-944D-1F839A13A444.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).